Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7407, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7407-01A (Primary Tumor).

(A) RESECTION OF FLOOR OF MOUTH AND ANTERIOR ARCH OF MANDIBLE, PARTIAL GLOSSECTOMY:
SQUAMOUS CARCINOMA INVADING MANDIBLE, margins of resection free of carcinoma.

DIAGNOSIS

- (A) RESECTION OF FLOOR OF MOUTH AND ANTERIOR ARCH OF MANDIBLE, PARTIAL GLOSSECTOMY:
SQUAMOUS CARCINOMA, MODERATELY DIFFERENTIATED WITH PERINEURAL INVOLVEMENT AND INFILTRATING SKELETAL MUSCLE (TUMOR SIZE=2.6 X 2.2 X 2.1 CM).
TUMOR EXTENDS TO RIGHT LINGUAL SURGICAL RESECTION MARGIN.
(SEE COMMENT)
Mandible (pending decalcification).
- (B) NEW RIGHT LINGUAL MARGIN:
Squamous mucosa and submucosa with no tumor present.

COMMENT

With submission of specimen B (new right lingual margin), the resection margins are free of tumor. Supplemental report to follow decalcification of mandible.

SPECIMEN

- (A) RESECTION OF FLOOR OF MOUTH AND ANTERIOR ARCH OF MANDIBLE, PARTIAL
(B) NEW RIGHT LINGUAL MARGIN:

SNOMED CODES

T-51200,M-80703

Source: NCI Genomic Data Commons file e5c05787-9c8a-42b0-9282-1349421cd535 (TCGA-CV-7407.CF467C20-267D-49C5-9484-FF1F69E9B99F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).